TARGET case TARGET-40-PALFYN — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c85f150-f994-5e5f-9f47-2b39737e71a0

Demographics
Sex at birth: female; Race: white; Age at index: 13 years; Vital status: Dead; Days to death: 1,003 days (2.7 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 13.3 years (4,841 days); Year of diagnosis: 2001; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,003 days (2.7 years).
   Treatment given: Protocol identifier: P9851.

Follow-up (2 entries)
- Days to follow up: 651 days (1.8 years); Progression or recurrence: Yes; Days to progression: 651 days (1.8 years); Days to first event: 651 days (1.8 years); First event: Relapse.
- Days to follow up: 1,003 days (2.7 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2004.

Biospecimens (2 samples)
- Sample TARGET-40-PALFYN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PALFYN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1003
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Primary site progression: Yes

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PALFYN-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 96
- % Non Tumor Nuclei: Top from Biopsy: 4
- % Cellular Tumor: Top from Biopsy: 90
- % Normal: Top from Biopsy: 8
- % Stroma: Top from Biopsy: 1
- % Necrosis: Top from Biopsy: 1
- % Tumor Nuclei: Bottom from Biopsy: 96
- % Non Tumor Nuclei: Bottom from Biopsy: 4
- % Cellular Tumor: Bottom from Biopsy: 89
- % Normal: Bottom from Biopsy: 9
- % Stroma: Bottom from Biopsy: 1
- % Necrosis: Bottom from Biopsy: 1
- PASS/FAIL: pass
